Somatic mutation profile of tumor specimen MP2PRT-PASKRT-TMP1-A (aliquot MP2PRT-PASKRT-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASKRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (877 days).
Specimen MP2PRT-PASKRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e660fbc-aac7-4283-821e-e13db701b2ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKRT-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3167f373-180e-49ce-b5e9-ac054c1e0c2a

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Intron 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL3 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 160/407 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1471065088; called by muse, mutect2, varscan2
- DDX53 | c.1661G>A p.R554K | Missense Mutation (SNP) | VAF 12/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60069558; called by muse, mutect2
- FAT4 | c.14126C>T p.S4709F | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1023681121, COSV58700247; called by muse, mutect2
- GPRIN1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1374149387; called by muse, mutect2
- HJURP | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV64978677; called by muse, mutect2, varscan2
- LRRIQ1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs777149304, COSV101279223, COSV67828147; called by muse, mutect2, varscan2
- NFKBIZ | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 42/678 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs189392097; called by muse, mutect2
- NKAIN4 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 60/645 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.097); catalogued as COSV64785451; called by muse, mutect2
- PCYOX1L | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs777617145; called by muse, mutect2, varscan2
- PIWIL2 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768769441, COSV63251525; called by muse, mutect2
- PTPN11 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV61009437, COSV99080320; called by muse, mutect2, varscan2
- RHOT1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 73/533 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61714033; called by muse, mutect2, varscan2
- SLC48A1 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 27/534 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1484292415; called by muse, mutect2
- TEX37 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 208/432 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV57556923; called by muse, mutect2, varscan2
- TMUB2 | c.178G>C p.D60H (on ENST00000538716 / NM_001353177.2; = p.D40H on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60228105; called by muse, mutect2
- TRPC5 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 27/565 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53287032; called by muse, mutect2
- ZNF761 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV61889544; called by muse, mutect2, varscan2
- ANKLE2 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- ANO4 | c.295G>C p.E99Q (on ENST00000392977 / NM_001286615.2; = p.E64Q on NM_178826.4) | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDIAS | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HIVEP2 | c.6937G>A p.D2313N | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2
- HJURP | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- NCOR1 | c.5857C>T p.Q1953* | Nonsense Mutation (SNP) | VAF 90/249 reads (36%) | called by muse, mutect2, varscan2
- NCR1 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 258/591 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR5D3P | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 11/383 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- PELO | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXNB3 | c.5292G>C p.L1764F | Missense Mutation (SNP) | VAF 14/515 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- POLK | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.047); called by muse, mutect2
- POTEB3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SLC43A1 | c.1572C>G p.F524L | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- STK3 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2
- USP34 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- ZNF480 | c.525A>T p.K175N | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.631); called by muse, mutect2
- ZNF585A | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 32/393 reads (8%) | called by muse, mutect2
- ADAMTS12 | c.2514G>A p.V838= | Silent (SNP) | VAF 94/230 reads (41%) | called by muse, mutect2, varscan2
- AHNAK | c.886C>T p.L296= | Silent (SNP) | VAF 28/517 reads (5%) | catalogued as rs1409666761; called by muse, mutect2
- ARR3 | c.795C>T p.F265= | Silent (SNP) | VAF 13/339 reads (4%) | called by muse, mutect2
- C6orf132 | c.207G>A p.L69= | Silent (SNP) | VAF 11/319 reads (3%) | catalogued as COSV59376630; called by muse, mutect2
- C9orf131 | c.483G>C p.V161= | Silent (SNP) | VAF 177/378 reads (47%) | called by muse, mutect2, varscan2
- CARM1 | c.807G>A p.L269= | Silent (SNP) | VAF 24/427 reads (6%) | called by muse, mutect2
- CHRD | c.594C>T p.F198= | Silent (SNP) | VAF 26/462 reads (6%) | catalogued as COSV52609061; called by muse, mutect2
- ENPP2 | c.2127C>T p.F709= (on ENST00000075322 / NM_001040092.3; = p.F761= on NM_006209.5) | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- FRRS1L | c.369C>G p.L123= | Silent (SNP) | VAF 29/403 reads (7%) | called by muse, mutect2
- KCNA5 | c.1233C>T p.F411= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as rs201975625; ClinVar: likely benign; called by muse, mutect2, varscan2
- MACC1 | c.1743C>T p.L581= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as rs552475136, COSV60546648; called by muse, mutect2
- MTCL1 | c.45G>A p.A15= | Silent (SNP) | VAF 60/542 reads (11%) | called by muse, mutect2, varscan2
- NXPE4 | c.414G>A p.L138= | Silent (SNP) | VAF 34/370 reads (9%) | catalogued as rs779311957; called by muse, mutect2
- POLQ | c.7077C>T p.F2359= | Silent (SNP) | VAF 32/426 reads (8%) | called by muse, mutect2
- GRAMD1B | c.1085-137C>G | Intron (SNP) | VAF 125/286 reads (44%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1485+161C>T | Intron (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- XPNPEP3 | c.64+3531G>A | Intron (SNP) | VAF 10/268 reads (4%) | catalogued as rs1357206270; called by muse, mutect2
